Surgical pathology report (de-identified scan), TCGA case TCGA-28-5208, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5208-01A (Primary Tumor).

[page 1 of 5]
Reviewed
NR
9/1/5

Patient: [REDACTED] Accession Number: [REDACTED]
Hospital No: [REDACTED] Pathologist: [REDACTED] Ordering M.D.: [REDACTED]
Date of Birth: [REDACTED] Assistant: [REDACTED]
Age/Sex: [REDACTED] Date of Procedure: [REDACTED] Copies To: [REDACTED]
Location: [REDACTED] Date Received: [REDACTED] TCGA - 28 - 5208

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV ✓

B. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 95% of tumor cellularity

C. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 95% of tumor cellularity

D. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 95% of tumor cellularity

E. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 2% of tumor necrosis
- 95% of tumor cellularity

F. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 90% of tumor cellularity

G. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #6:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

H. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #7:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

I. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #8:

- Glioblastoma multiforme, WHO grade IV

Patient Case(s): [REDACTED]

[page 2 of 5]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

- 0% of tumor necrosis
- 95% of tumor cellularity

J. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #9:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

K. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, NCI #10:

- Glioblastoma multiforme, WHO grade IV
- 0% of tumor necrosis
- 95% of tumor cellularity

L. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

M. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY, CLINICAL TRIAL:

- Glioblastoma multiforme, WHO grade IV
- 2% of tumor necrosis

N. BRAIN, RIGHT FRONTAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

Comment:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the low 5% result in this case suggests a likelihood of this tumor being responsive to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED].

[REDACTED] subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED].

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

[page 3 of 5]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Right frontal tumor ✓

MICROSCOPIC FINDINGS:

This infiltrating astrocytoma is composed of ungulate moderately sized nuclei featuring numerous mitotic figures and associated with florid endothelial proliferation.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
MGMT	N1	Up to 5%
PTEN	N1	Retained (2-3+)
pMAPK	N1	Up to 60% of tumor nuclei and 80% of tumor cytoplasm is positive
Laminin beta-1 (8/411)	N1	Upregulated (3+)
Laminin beta-2 (9/421)	N1	Focal paranuclear retention (1+)
EGFR by FISH	N1	Pending

GROSS:

A. RIGHT FRONTAL FS #1

Labeled with the patient's name, labeled "right frontal" and received fresh for intraoperative consultation and subsequently fixed in formalin is three portions of brown-tan tissue ranging in size from 0.3 to 0.7 cm in greatest dimension.

Entirely submitted.

A1. FSA1 - 2

A2. Remaining unfrozen tissue - 2

B. RIGHT FRONTAL NCI #1

Labeled with the patient's name, labeled "right frontal NCI #1" and received fresh and subsequently fixed in formalin is a 1.6 x 1.0 x 0.3 cm portion of pink-tan tissue. Entirely submitted.

B1. 1

C. RIGHT FRONTAL NCI #2

Labeled with the patient's name, labeled "right frontal NCI #2" and received fresh and subsequently fixed in formalin is a 1.5 x 0.5 x 0.5 cm portion of tan tissue. Entirely submitted.

C1. 1

D. RIGHT FRONTAL NCI #3

Labeled with the patient's name, labeled "right frontal NCI #3" and received fresh and subsequently fixed in formalin is a 1.0 x 0.5 x 0.5 cm portion of tan tissue. Entirely submitted.

D1. 1

E. RIGHT FRONTAL NCI #4

Labeled with the patient's name, labeled "right frontal NCI #4" and received fresh and subsequently fixed in formalin is a 1.3 x 0.5 x 0.4 cm portion of tan tissue. Entirely submitted.

E1. 1

F. RIGHT FRONTAL NCI #5

Labeled with the patient's name, labeled "right frontal NCI #5" and received fresh and subsequently fixed in formalin are two portions of tan tissue measuring 1.0 x 0.7 x 0.3 cm and 1.0 x 0.4 x 0.3 cm. Entirely submitted.

[page 4 of 5]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

F1. 2

G. RIGHT FRONTAL NCI #6

Labeled with the patient's name, labeled "right frontal NCI #6" and received fresh is a 1.5 x 0.7 x 0.3 cm portion of tan tissue. Entirely submitted.

G1. 1

H. RIGHT FRONTAL NCI #7

Labeled with the patient's name, labeled "right frontal NCI #7" and received fresh is a 1.4 x 0.7 x 0.5 cm portion of tan tissue. Entirely submitted.

H1. 1

I. RIGHT FRONTAL NCI #8

Labeled with the patient's name, labeled "right frontal NCI #8" and received fresh are three portions of tan tissue measuring 0.5 to 1.2 cm in greatest dimension. Entirely submitted.

I1. 3

J. RIGHT FRONTAL NCI #9

Labeled with the patient's name, labeled "right frontal NCI #9" and received fresh is a 1.4 x 0.7 x 0.4 cm portion of tan tissue. Entirely submitted.

J1. 1

K. RIGHT FRONTAL NCI #10

Labeled with the patient's name, labeled "right frontal NCI #10" and received fresh is a 0.8 x 0.8 x 0.5 cm fragment of tan-gray tissue. Entirely submitted.

K1. 1

L. RIGHT FRONTAL PERMANENT

Labeled with the patient's name, labeled "right frontal" and received formalin are several portions of tan tissue ranging in size from 0.5 to 2.9 cm in greatest dimension. Entirely submitted.

L1. 5

L2. 4

M. RIGHT FRONTAL CLINICAL TRIAL STUDY

Labeled with the patient's name, labeled "right frontal clinical trial study" and received in formalin are two portions of tan tissue, measuring 1.2 and 1.3 cm in greatest dimension. Entirely submitted.

M1. 2

N. BRAIN TUMOR

Labeled with the patient's name, labeled "brain tumor" and received in formalin is a 2.2 x 1.5 x 1.0 cm portion of tissue.

Entirely submitted.

N1, N2. 2 each

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN AND TP):

A. RIGHT FRONTAL FS AND TP:

- High-grade glioma

[page 5 of 5]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

[REDACTED]
I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
[REDACTED] Electronically signed [REDACTED]

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED] Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 1944b484-ee04-4621-86c8-2ea751f103c6 (TCGA-28-5208.C683E7A3-F811-4F52-BCCE-CF6EEA75DF12.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).